Surgical pathology report (de-identified scan), TCGA case TCGA-SL-A6J9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-SL-A6J9-01A (Primary Tumor).

Pathology Report

Date of Surgery:

Pathologic Diagnosis:

Endometrioid Adenocarcinoma

FIGO grade 3 (greater than 50% nonsquamous solid growth with foci of grade 3 nuclear cytology)

Pathologic staging: (pTNM [FIGO]) : pT1b, pNO, pMx [1B] (AJCC/UICC TNM 7th edition)

Additional pathologic findings:

- uterine cervix with mild chronic cervicitis and squamous metaplasia
- Leiomyoma
- Adenomyosis
- Bilateral fallopian tubes without specific histopathologic alteration

Ancillary studies: Tumor nuclei are positive for MLH-1, MSH-2, MSH6 and PMS-2 by immunohistochemistry. The neoplasm is considered microsatellite stable. Cervical invasion not present.

ICD-O-3

Adenocarcinoma, endometrioid NOS

8380/3

Site Endometrium C54.1

DD 6/28/13

Source: NCI Genomic Data Commons file 1680ff56-3063-4b3d-a049-3ca39a4a109f (TCGA-SL-A6J9.DFD43EFD-E91F-487F-A737-93C57C065A49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).